Gene-level copy-number profile of tumor specimen TCGA-CD-A486-01A from TCGA case TCGA-CD-A486, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 68.1 years (24,879 days).
Specimen TCGA-CD-A486-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.57eaefe8-c04b-4ec8-b786-a8a9dd6b5db1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-A486-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 834 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/740230bb-fbf7-4aad-b209-9d3b0f8ce9c7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 14; copy number 2: 9,697; copy number 3: 17,372; copy number 4: 19,313; copy number 5: 2,425; copy number 6: 6,455; copy number 7: 1,896; copy number 8: 757; copy number 9: 331; copy number 10: 516; copy number 11: 511; copy number 12: 30; copy number 13: 9; copy number 14: 287; copy number 16: 2; copy number 17: 14; copy number 18: 47; copy number 19: 4; copy number 22: 40; copy number 23: 28; copy number 27: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-A486-01A-11D-A24C-01): tumor purity 0.57, ploidy 3.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:56,885,284–57,315,909, 9 genes: RN7SKP6, PRR20A, PRR20C, PRR20B, PRR20D, PRR20E, PRR20FP, MTCO2P3, SLC25A5P4.
- chr18:50,795,120–51,283,896, 11 genes: MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,840 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,052,566–148,679,779, 86 genes, copy number 10 (broad region; genes not listed).
- chr1:149,754,301–152,196,699, 143 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr2:103,109,759–104,757,719, 26 genes, copy number 14: AC073987.1, AC010881.1, AC011593.1, CRLF3P1, AC018880.1, CAPZBP1, AC013727.1, AC013727.2, LINC01965, AC013727.3, AC096554.1, AHCYP3, AC068535.1, LINC01831, AC068535.2, LINC01102, LINC01103, AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2, SNORA72, LINC01114.
- chr2:107,254,691–107,407,329, 2 genes, copy number 16 (within-gene range 4–16): LINC01789, AC096669.1.
- chr4:386,174–1,745,171, 53 genes, copy number 10: AC092574.2, ZNF519P4, AC092574.1, ABCA11P, ZNF721, PIGG, TMEM271, AC116565.1, PDE6B, PDE6B-AS1, AC107464.2, ATP5ME, MYL5, SLC49A3, PCGF3, AC107464.1, AC139887.4, AC139887.2, AC139887.1, CPLX1, AC139887.3, AC139887.5, GAK, TMEM175, DGKQ, SLC26A1, IDUA, FGFRL1, AC019103.1, RNF212, AC092535.3, AC092535.4, TMED11P, AC092535.1, AC092535.2, SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT, MAEA, UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129.
- chr4:122,618,983–124,339,047, 23 genes, copy number 9 (within-gene range 4–9): IL21-AS1, AC053545.1, CETN4P, BBS12, AC021205.2, FGF2, AC021205.1, AC021205.3, NUDT6, SPATA5, AC026402.1, AC026402.2, SPRY1, AC093821.1, LINC02435, LINC01091, AC096732.1, RPL21P50, AC093767.1, AC108075.1, PPIAP76, AC121154.1, AC133530.1.
- chr6:30,876,421–31,225,058, 28 genes, copy number 11: DDR1, MIR4640, GTF2H4, AL669830.1, VARS2, SFTA2, Y_RNA, MUCL3, HCG21, NAPGP2, MUC21, MUC22, HCG22, RNU6-1133P, C6orf15, PSORS1C1, CDSN, PSORS1C2, POLR2LP1, CCHCR1, TCF19, POU5F1, PSORS1C3, AL662844.4, HCG27, AL662844.3, AL662844.1, AL662844.2.
- chr6:43,213,801–44,830,188, 62 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr7:2,251,770–2,354,318, 1 gene, copy number 11 (within-gene range 7–11): SNX8.
- chr7:2,287,915–2,614,733, 10 genes, copy number 11 (within-gene range 7–11): IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE.
- chr7:10,901,978–17,467,256, 71 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr7:46,673,785–48,647,497, 20 genes, copy number 9 (within-gene range 7–9): AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13.
- chr7:50,590,063–50,793,462, 1 gene, copy number 9 (within-gene range 7–9): GRB10.
- chr7:50,839,363–55,344,958, 53 genes, copy number 9–11: AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr7:55,887,277–62,275,678, 115 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr7:87,151,422–89,496,918, 32 genes, copy number 14: AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1.
- chr7:89,882,353–94,077,157, 74 genes, copy number 9–23 (within-gene range 8–23) (broad region; genes not listed).
- chr7:100,509,416–100,968,347, 30 genes, copy number 12 (within-gene range 5–12): AC069281.1, RN7SL416P, AGFG2, IRS3P, SAP25, AC069281.2, LRCH4, FBXO24, PCOLCE-AS1, PCOLCE, MOSPD3, TFR2, ACTL6B, GNB2, GIGYF1, POP7, EPO, ZAN, EPHB4, RN7SL750P, SLC12A9, SLC12A9-AS1, TRIP6, MIR6875, SRRT, UFSP1, ACHE, RN7SL549P, RPS29P15, MUC3A.
- chr7:106,372,251–106,770,207, 1 gene, copy number 9 (within-gene range 4–9): AC004917.1.
- chr7:106,569,876–108,003,213, 29 genes, copy number 9 (within-gene range 4–9): AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1.
- chr8:82,862,779–85,379,014, 26 genes, copy number 10 (within-gene range 7–10): AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419, AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1.
- chr8:86,707,547–87,615,219, 4 genes, copy number 14 (within-gene range 7–14): AC090572.3, AC090572.2, AC090572.1, CNBD1.
- chr8:89,585,872–102,452,483, 253 genes, copy number 13–18 (broad region; genes not listed).
- chr12:43,835,967–47,079,959, 42 genes, copy number 10 (within-gene range 5–10): TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2.
- chr13:30,340,267–31,846,539, 29 genes, copy number 11: LINC00426, AL356750.1, AL161893.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, AL158065.1, WDR95P, HSPH1, B3GLCT, ANKRD26P4, AL161616.2, AL161616.1, RXFP2, AL138708.1.
- chr13:31,952,580–31,975,448, 3 genes, copy number 11: EEF1DP3, AC002525.1, Metazoa_SRP.
- chr13:97,675,011–114,337,626, 271 genes, copy number 11 (broad region; genes not listed).
- chr15:50,494,018–51,005,895, 12 genes, copy number 11 (within-gene range 6–11): USP50, TRPM7, AC084756.1, AC084756.2, RN7SL354P, SPPL2A, AC012100.3, AC012100.2, AC012100.1, AC021752.1, AP4E1, DCAF13P3.
- chr17:26,981,694–27,626,438, 20 genes, copy number 10 (within-gene range 5–10): AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1.
- chr18:7,566,782–22,933,764, 270 genes, copy number 9–22 (within-gene range 2–22) (broad region; genes not listed).
- chr19:29,287,011–30,085,893, 21 genes, copy number 27 (within-gene range 2–27): AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr19:30,850,975–31,787,255, 15 genes, copy number 13–22: AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P.
- chr20:17,956,979–18,113,579, 8 genes, copy number 11 (within-gene range 6–11): OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA.
- chr20:53,552,770–53,827,297, 6 genes, copy number 10: AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
